Somatic mutation profile of tumor specimen TCGA-A6-6138-01A (aliquot TCGA-A6-6138-01A-11D-1771-10) from TCGA case TCGA-A6-6138, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 61.7 years (22,523 days).
Specimen TCGA-A6-6138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c805598-428f-48c4-969b-84b43b7aa7e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6138-10A (Blood Derived Normal), aliquot TCGA-A6-6138-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5808dd2-76d5-473a-a41a-d9a5020e1581

The open-access MAF lists 122 somatic variants for this specimen: 86 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 34, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, Splice Region 2, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 97/170 reads (57%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 105/192 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99589630; called by muse, varscan2
- ACAP2 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); catalogued as COSV58751889; called by muse, mutect2, varscan2
- ADGRA2 | c.2031del p.V678Sfs*14 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV100177539; called by mutect2, pindel, varscan2
- ALG14 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64634839; called by muse, mutect2, varscan2
- ARID2 | c.1023G>C p.E341D | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV100536221, COSV57604812; called by muse, mutect2
- ASTN2 | c.2899G>A p.D967N (on ENST00000313400 / NM_001365069.1; = p.D916N on NM_014010.5) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56004303; called by muse, mutect2, varscan2
- C3orf20 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs542764490, COSV53785335; called by mutect2, varscan2
- CACNA1E | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as rs374689888, COSV62395329; called by muse, mutect2, varscan2
- CADPS | c.3398C>A p.S1133* | Nonsense Mutation (SNP) | VAF 46/141 reads (33%) | catalogued as COSV51879305; called by muse, mutect2, varscan2
- CCDC87 | c.1453A>G p.N485D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV59579061; called by muse, mutect2, varscan2
- CLDND1 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57858794; called by muse, mutect2, varscan2
- COL27A1 | c.3916G>A p.G1306R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61925918; called by muse, mutect2, varscan2
- DDX39B | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 31/129 reads (24%) | catalogued as COSV66019250; called by muse, mutect2, varscan2
- DENND2D | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62959125; called by muse, mutect2, varscan2
- DISP1 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs148545972, COSV52658687; called by muse, mutect2, varscan2
- DLGAP4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762577016, COSV59422245; called by muse, mutect2, varscan2
- DNM1 | c.386-1G>C p.X129_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100359928; called by muse, mutect2, varscan2
- ECEL1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs569210107, COSV58811046; called by muse, mutect2, varscan2
- ENY2 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV53456852; called by muse, mutect2, varscan2
- FAM166A | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV61116604; called by muse, mutect2, varscan2
- FAT1 | c.13546C>T p.H4516Y | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101499352, COSV101499415; called by muse, mutect2, varscan2
- FGF14 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs367707894; called by muse, mutect2, varscan2
- FLNB | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55879102; called by muse, mutect2, varscan2
- FOXD4 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1381596598, COSV100070927; called by muse, mutect2, varscan2
- FRY | c.5789A>G p.D1930G | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV66570036; called by muse, mutect2, varscan2
- GALNT13 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.776); catalogued as COSV101223014; called by muse, mutect2, varscan2
- GALNT17 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768467394, COSV61156096, COSV61169634; called by muse, mutect2, varscan2
- GLB1L2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144822077; called by muse, mutect2, varscan2
- HTR3A | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs144629647; called by muse, mutect2, varscan2
- IFI16 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as rs1232818629, COSV55538098; called by muse, mutect2, varscan2
- JPH3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs772600210, COSV52467539; called by muse, mutect2, varscan2
- KIAA0408 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as rs779822528, COSV64106510; called by muse, mutect2, varscan2
- KRT2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs530945813, COSV59010376; called by muse, mutect2, varscan2
- KRTAP10-3 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV59961671; called by muse, mutect2, varscan2
- LAMA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780440007, COSV67531188; called by muse, mutect2, varscan2
- LHX5 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55662779; called by muse, mutect2, varscan2
- LIFR | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs757892555, COSV54689883; called by muse, mutect2, varscan2
- LMO7 | c.330A>G p.I110M (on ENST00000357063; = p.I125M on NM_005358.5) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58536240; called by muse, mutect2, varscan2
- LSAMP | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61290093; called by muse, mutect2, varscan2
- MAB21L4 | c.1328G>C p.G443A (on ENST00000388934 / NM_001085437.3; = p.G275A on NM_024861.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56743402; called by muse, mutect2
- MAP1B | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs945981683, COSV57098748; called by muse, mutect2, varscan2
- ME3 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369256814; called by muse, mutect2, varscan2
- METTL14 | c.803A>C p.N268T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.843); catalogued as COSV66310593; called by muse, mutect2, varscan2
- MGAM | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV72074615; called by muse, mutect2, varscan2
- MKNK2 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51732377; called by muse, mutect2, varscan2
- MLH1 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776643257, COSV99212463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MON2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.434); catalogued as COSV54807009; called by muse, mutect2, varscan2
- MYH15 | c.38T>A p.F13Y | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV56309712; called by muse, mutect2, varscan2
- MYO3A | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746307707, COSV56318875, COSV99780654; called by muse, mutect2, varscan2
- NCKAP5 | c.2596C>A p.P866T | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs369688401, COSV58427396; called by muse, mutect2, varscan2
- NLGN4Y | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.346); catalogued as rs1309159261, COSV59296245; called by muse, mutect2, varscan2
- NRP2 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as rs143177221, COSV99785552; called by muse, mutect2, varscan2
- OR2C1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59240183; called by muse, mutect2, varscan2
- OTUD7B | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.196); catalogued as COSV64916075; called by muse, mutect2, varscan2
- PARP3 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1333166723, COSV67168484; called by muse, mutect2, varscan2
- PAX6 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.648); catalogued as CP984557, COSV53793322; called by muse, mutect2, varscan2
- PLCG2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1325870340, COSV63867967; called by muse, mutect2, varscan2
- POT1 | c.23A>C p.N8T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62929886, COSV62930168; called by muse, varscan2
- PSME4 | c.4154G>A p.G1385D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66364880; called by muse, mutect2, varscan2
- RANBP3 | c.1103C>T p.S368F (on ENST00000340578 / NM_007322.3; = p.S363F on NM_003624.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50381539; called by muse, mutect2, varscan2
- SDCBP2 | c.349G>A p.G117S (on ENST00000339987 / NM_001199784.1; = p.G32S on NM_015685.5) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV60589309; called by muse, mutect2, varscan2
- SEMA6C | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59002865; called by muse, mutect2
- SLC25A35 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs991129590, COSV56839416; called by muse, mutect2, varscan2
- SLC6A19 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs201212000, CM102329, COSV58671168; called by muse, mutect2, varscan2
- SLC6A5 | c.1395G>T p.T465= | Splice Region (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54226416; called by muse, mutect2, varscan2
- TAF2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1340243028, COSV58087056; called by muse, mutect2, varscan2
- TGFBR1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564161322, CM165735, COSV66624829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC2 | c.4279del p.S1427Vfs*49 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs137854113; ClinVar: not provided; called by mutect2, pindel, varscan2
- TTC14 | c.1262C>G p.A421G | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV56011020; called by muse, mutect2, varscan2
- TTN | c.55880A>C p.K18627T (on ENST00000591111; = p.K11203T on NM_003319.4) | Missense Mutation (SNP) | VAF 53/174 reads (30%) | PolyPhen benign (0.022); catalogued as COSV60049034; called by muse, mutect2, varscan2
- TULP4 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100893501; called by muse, mutect2, varscan2
- UNC13C | c.2140T>G p.L714V | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV52871597; called by muse, mutect2, varscan2
- UNC13C | c.3228G>A p.L1076= | Splice Region (SNP) | VAF 22/56 reads (39%) | catalogued as COSV52871624, COSV99520848; called by muse, mutect2, varscan2
- VCX3B | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 383/752 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs368402392, COSV66842494; called by muse, mutect2, varscan2
- WDR81 | c.4162C>T p.P1388S (on ENST00000409644 / NM_001163809.2; = p.P337S on NM_152348.4) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777833436, COSV58482641; called by muse, mutect2, varscan2
- ZFP57 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.308); catalogued as COSV65306105; called by muse, mutect2, varscan2
- ZMYM6 | c.3932C>T p.T1311I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV64120885; called by muse, mutect2, varscan2
- ZNF217 | c.2770G>A p.V924M | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.302); catalogued as rs376210645, COSV56602427; called by muse, mutect2, varscan2
- ZNF646 | c.3931G>A p.A1311T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs373261909, COSV54924210; called by muse, mutect2, varscan2
- PLCB4 | c.1479dup p.E494Rfs*4 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- SELL | c.177dup p.P60Tfs*8 (on ENST00000650983; = p.P47Tfs*8 on NM_000655.5) | Frame Shift Ins (INS) | VAF 68/203 reads (33%) | called by mutect2, pindel, varscan2
- TSC2 | c.718_720del p.I240del | In Frame Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- UCKL1 | c.654+1del p.X218_splice | Splice Site (DEL) | VAF 121/238 reads (51%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5325G>A p.A1775= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs375331989; called by muse, mutect2, varscan2
- APOB | c.7035C>T p.I2345= | Silent (SNP) | VAF 46/194 reads (24%) | catalogued as rs368113811, COSV51935584; called by muse, mutect2, varscan2
- ARHGEF10 | c.1470C>T p.S490= (on ENST00000398564; = p.S465= on NM_014629.4) | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs529282966, COSV50649323; called by muse, mutect2, varscan2
- AURKC | c.111C>T p.R37= (on ENST00000302804 / NM_001015878.2; = p.R3= on NM_003160.3) | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV57138527; called by muse, mutect2, varscan2
- BEND6 | c.819T>C p.L273= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV66068913; called by muse, mutect2, varscan2
- BICRAL | c.2196A>G p.R732= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs1163803778, COSV100018083; called by muse, mutect2, varscan2
- BSN | c.7062C>T p.F2354= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs755279303, COSV56513414, COSV56517698; called by muse, mutect2, varscan2
- CEMIP2 | c.3342A>G p.Q1114= | Silent (SNP) | VAF 58/209 reads (28%) | catalogued as rs1317088789, COSV65484540; called by muse, mutect2, varscan2
- CSMD1 | c.5352C>T p.S1784= (on ENST00000520002; = p.S1783= on NM_033225.6) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs539146933, COSV59324419; called by muse, mutect2
- EDC4 | c.3345G>A p.R1115= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV59302713; called by muse, mutect2, varscan2
- FREM2 | c.9198T>A p.G3066= | Silent (SNP) | VAF 24/191 reads (13%) | catalogued as COSV99748821; called by muse, mutect2, varscan2
- IRF2BP2 | c.1299C>T p.D433= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs752521894, COSV64014946; called by muse, mutect2, varscan2
- MATN1 | c.1017G>A p.K339= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs1241122485, COSV65651323; called by muse, mutect2, varscan2
- MIB1 | c.1386T>C p.C462= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55090386; called by muse, mutect2, varscan2
- OTUD4 | c.2769C>T p.L923= (on ENST00000447906 / NM_001366057.1; = p.L858= on NM_001102653.1) | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as COSV71381842; called by muse, mutect2
- PCDHA11 | c.1029C>T p.N343= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs371110623; called by muse, mutect2, varscan2
- PCDHA9 | c.1764C>T p.G588= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as COSV100969529; called by muse, varscan2
- PCDHB8 | c.1344C>T p.N448= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as rs1554281186, COSV50753525; called by muse, mutect2, varscan2
- PCDHGA8 | c.2052G>A p.P684= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV99539878; called by muse, mutect2
- PDE6B | c.2478G>A p.E826= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55326334; called by muse, mutect2, varscan2
- PIK3CG | c.624G>A p.P208= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs756654814, COSV63248434; called by muse, mutect2, varscan2
- PLEKHG4B | c.3315G>A p.R1105= (on ENST00000283426; = p.R1461= on NM_052909.5) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV52047235; called by muse, mutect2, varscan2
- POLD1 | c.3000C>T p.G1000= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs766451656, COSV54530574; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTCHD4 | c.942C>T p.S314= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs771392397, COSV100260859; called by muse, mutect2, varscan2
- PTGFRN | c.297C>T p.N99= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV67798431; called by muse, mutect2, varscan2
- SIGLEC10 | c.972A>T p.R324= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as COSV100218993; called by muse, mutect2, varscan2
- SNTG1 | c.942T>C p.C314= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV52442489; called by muse, mutect2, varscan2
- TDRD6 | c.4155G>A p.V1385= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV60175615; called by muse, mutect2, varscan2
- TGM6 | c.1188C>T p.N396= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs145029765; called by muse, mutect2, varscan2
- TMEM26 | c.1032C>T p.N344= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs767436748, COSV53262121; called by muse, mutect2, varscan2
- TTC3 | c.2145C>T p.T715= | Silent (SNP) | VAF 98/307 reads (32%) | catalogued as COSV100695537; called by muse, mutect2, varscan2
- TUBA3E | c.96C>T p.P32= | Silent (SNP) | VAF 87/260 reads (33%) | catalogued as rs760877722, COSV57270202; called by muse, mutect2, varscan2
- ZMIZ2 | c.450T>G p.A150= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs759278580, COSV99536901; called by mutect2, varscan2
- ZNF536 | c.1992G>T p.L664= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100835239, COSV100835248; called by muse, mutect2, varscan2
- DSCR4 | n.123G>A | RNA (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100077206, COSV100077375, COSV60300147; called by muse, mutect2, varscan2
- NRG1 | c.502+31226G>T | Intron (SNP) | VAF 39/101 reads (39%) | catalogued as COSV55158842; called by muse, mutect2, varscan2
